Surgical pathology report (de-identified scan), TCGA case TCGA-L3-A524, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Gundersen Lutheran Health System, specimen TCGA-L3-A524-01A (Primary Tumor).

[page 1 of 3]
Patient:

Med. Record. No.:

Date of Birth:

Submitted by:

Report also to:

Sex: F

Pathology #:

Date of Procedure:

Date Received:

Pathology Report

DIAGNOSIS:

ICD-0-3
carcinoma, squamous cell, NOS
8070/3
Site: lung, upper lobe C34.1
hw 11/7/12

SPECIMEN

Specimen type: Right upper lobectomy with en bloc resection of chest wall and portion of lower lobe

Tumor site: Right upper lobe

Additional tumor location info: Tumor extends into right lower lobe and chest wall with invasion into the rib.

TUMOR

Histologic type: Squamous cell carcinoma

Histologic grade: Poorly differentiated (G3 of 4)

Tumor size: 6.4cm

Tumor focality: Unifocal

Direct extension of tumor: Tumor invades adjacent structure(s):
Chest wall
Rib

Tumor-associated atelectasis/obstructive pneumonitis: Absent

Lymphovascular space invasion: Absent

Additional findings: None

MARGINS

All margins negative for carcinoma

Distance to nearest margin: 3.2cm

Nearest margin: right lower lobe parenchymal margin.

LYMPH NODES

All sampled lymph nodes are benign

Number of nodes evaluated: 8

Comment:

The 8 lymph nodes include 7 nodes from the lobectomy specimen (Part A) and one, right pulmonary lymph node (Part B)

STAGING (AJCC)

Primary Tumor: pT3

Lymph Nodes: pN0

[page 2 of 3]
Patient:
Med. Record. No.: [REDACTED]
Date of Birth: [REDACTED]
Submitted by: [REDACTED]
Report also to: [REDACTED]

Sex: F

Pathology #: [REDACTED]
Date of Procedure:
Date Received:

Pathology Report

- B. Right pulmonary lymph node:
Lymph node (1), negative for malignancy.

CLINICAL INFORMATION:

Lung mass, tissue taken by [REDACTED] for the

SPECIMEN(S) RECEIVED:

- A. Right upper lobectomy with en bloc resection of chest wall & portion of lower lobe – stitch
B. Right pulmonary lymph node

GROSS DESCRIPTION:

A. Received fresh is a 477-gram, 13 x 11 x 6 cm resection of the right upper lobe lung, attached 7 x 5 x 3 cm portion of the right lower lobe and attached 11 x 8 x 3.8 cm resection of the right chest wall which includes three ribs and surrounding red-yellow soft tissue. The pleural surface is dusky and pink-purple with a large amount of black anthracotic pigment present. There is a large 6.4 x 5 x 4.5 cm gray-white to gray-black mass extending from the lower portion of the upper lobe into the attached portion of lower lobe and into the attached portion of chest wall. The lesion appears grossly to come within 3.2 cm of the staple line on the lower lobe and appears grossly to invade into the central rib bone. The tumor grossly extends to within 3.2 cm of the peripheral margin of the resected chest wall. The lung tissue unaffected by tumor is soft, spongy and dark red to gray-black. There are numerous soft, gray-black anthracotic lymph nodes present at the hilum. Representative sections are submitted as A1 – bronchial margin for frozen section; A2 – peripheral chest wall margin for frozen section; A3 – en face margin from staple line on right lower lobe; A4-A6 – mass (A4 & A6 include tumor involving RLL); A7 – normal lung; A8 – hilar lymph node, bisected; A9-A10 – intact hilar lymph nodes; A11-A12 – invasion of tumor into rib bone after decalcification.

FROZEN SECTION DIAGNOSIS: Bronchial resection margin and chest wall margin negative for malignancy.
Called to at by [REDACTED]

B. Received in formalin is a 1.2 x 0.6 x 0.5 cm gray-black lymph node. Bisected and submitted in B1.

Immunohistochemistry Results

Formalin-fixed, paraffin-embedded tissue is utilized. Tissue sections are incubated with the following antibodies. Positive and negative controls stain appropriately. Complete procedural methodology is available upon request. Results indicated below:

Material: Block A5

Marker For:	Result	Comment
TTF-1	Negative	

[page 3 of 3]
Patient: [REDACTED]

MRN: [REDACTED]

p63	Positive	
CD56	Negative	

Note: The performance characteristics of all immunohistochemical stains cited in this report were determined by the [REDACTED] at [REDACTED] as part of an ongoing quality assurance program and in compliance with federally mandated regulations drawn from the [REDACTED]. Some of these tests may rely on the use of "analyte specific reagents" and have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. Nevertheless, federal rules concerning the medical use of analyte specific reagents require that the following disclaimer be attached to this report. These tests are used for clinical purposes and should not be regarded as investigational or for research. The immunohistochemistry laboratory at [REDACTED] is certified by the [REDACTED] and I [REDACTED] as a high complexity laboratory under [REDACTED].

Slides were microscopically examined by the pathologist.

Evaluation performed by [REDACTED]

Electronically signed [REDACTED]

Pathology Report

Page 3 of 3

Source: NCI Genomic Data Commons file 5d1bf5ab-64b0-4107-aff9-54063853cd17 (TCGA-L3-A524.9E78715F-BAED-4724-A4DC-C432C9C26CCF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).